Somatic mutation profile of tumor specimen TCGA-IN-A7NT-01A (aliquot TCGA-IN-A7NT-01A-21D-A34U-08) from TCGA case TCGA-IN-A7NT, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 73.2 years (26,727 days).
Specimen TCGA-IN-A7NT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2841ab4f-8cd4-4472-b27b-a1101fd395f7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-IN-A7NT-10A (Blood Derived Normal), aliquot TCGA-IN-A7NT-10A-01D-A34X-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b5398212-8246-4b3a-8ed5-0e5f69e25572

The open-access MAF lists 126 somatic variants for this specimen: 90 protein-altering or splice-affecting, 34 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 79, Silent 34, Nonsense Mutation 3, Intron 2, Splice Site 1, Splice Region 1, Translation Start Site 1, Frame Shift Ins 1, Nonstop Mutation 1, In Frame Del 1, Frame Shift Del 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SMARCA4 | c.2729C>T p.T910M | Missense Mutation (SNP) | VAF 7/22 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1238758086, COSV60785486, COSV60802491; ClinVar: other / uncertain significance; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 26/69 reads (38%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCB1 | c.596C>A p.T199K | Missense Mutation (SNP) | VAF 48/255 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.774); catalogued as COSV99712537; called by muse, mutect2, varscan2
- BCAT2 | c.511C>A p.P171T | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60273789; called by muse, mutect2, varscan2
- BEND2 | c.1243G>T p.D415Y | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.648); catalogued as COSV101191815, COSV101191908; called by muse, mutect2, varscan2
- BLZF1 | c.28+1G>A p.X10_splice | Splice Site (SNP) | VAF 4/16 reads (25%) | catalogued as COSV100250559; called by mutect2, varscan2
- BSN | c.10987G>A p.G3663R | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs1218069449, COSV99607816; called by muse, mutect2, varscan2
- CDKN2A | c.67G>C p.G23R | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM024657, CM056560, CM056561, COSV100446060, COSV100446547, COSV58709325; called by muse, mutect2, varscan2
- CGAS | c.1127G>T p.R376L | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100943643, COSV64808063; called by muse, mutect2, varscan2
- CRACR2B | c.975G>T p.R325S (on ENST00000525077 / NM_001286606.2; = p.E270* on NM_173584.4) | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.026); catalogued as COSV100431735; called by muse, mutect2, varscan2
- CRISPLD1 | c.127G>T p.D43Y | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); catalogued as COSV100081766, COSV51553118; called by muse, mutect2, varscan2
- DMD | c.8348A>C p.N2783T | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV100626544; called by muse, mutect2, varscan2
- EEF1E1 | c.211G>A p.V71I | Missense Mutation (SNP) | VAF 13/150 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0.199); catalogued as rs143820451, COSV65675455; called by muse, mutect2
- ELOA2 | c.1366A>G p.S456G | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT tolerated (0.31); PolyPhen benign (0.418); catalogued as COSV99796247; called by muse, mutect2, varscan2
- FAT4 | c.12000T>G p.I4000M | Missense Mutation (SNP) | VAF 35/80 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV100627933; called by muse, mutect2, varscan2
- FMR1 | c.223G>C p.E75Q | Missense Mutation (SNP) | VAF 17/158 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99503130; called by muse, mutect2, varscan2
- FRYL | c.7139C>T p.S2380L | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51961754; called by muse, mutect2, varscan2
- GCK | c.1129C>T p.R377C | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1471992838, CM068318, CM096930, COSV56269191; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HECW2 | c.458C>T p.T153M | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs752174006, COSV99646524; called by muse, varscan2
- HMBS | c.67G>A p.V23M | Missense Mutation (SNP) | VAF 36/91 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.258); catalogued as rs776931683, COSV99597874; called by muse, mutect2, varscan2
- HNRNPL | c.605C>T p.P202L | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99670163; called by muse, mutect2, varscan2
- IGKV1D-16 | c.34C>A p.L12I | Missense Mutation (SNP) | VAF 31/127 reads (24%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.894); catalogued as rs369645871; called by muse, mutect2, varscan2
- KCNAB3 | c.635G>A p.R212Q | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs767486615, COSV58140626; called by muse, mutect2, varscan2
- KLC4 | c.859T>A p.L287M | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99431591; called by muse, mutect2, varscan2
- KLHL1 | c.1476G>A p.M492I | Missense Mutation (SNP) | VAF 22/130 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.673); catalogued as COSV100917127; called by muse, mutect2, varscan2
- LRP1B | c.5081A>C p.K1694T | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.722); catalogued as COSV67220150; called by muse, mutect2, varscan2
- LRRC37A3 | c.3937C>T p.R1313C | Missense Mutation (SNP) | VAF 80/284 reads (28%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.454); catalogued as rs139741056, COSV58536196; called by muse, mutect2, varscan2
- MAGEA1 | c.484G>T p.A162S | Missense Mutation (SNP) | VAF 30/124 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.396); catalogued as COSV100756628; called by muse, mutect2, varscan2
- MAP7D2 | c.2165C>T p.P722L | Missense Mutation (SNP) | VAF 29/112 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101107267; called by muse, mutect2, varscan2
- MCF2L | c.76G>A p.E26K | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); catalogued as COSV65100927; called by muse, mutect2, varscan2
- MED25 | c.943G>A p.G315R | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs1483220422, COSV57203178; called by muse, mutect2, varscan2
- MN1 | c.3088G>A p.G1030S | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as rs1480513294, COSV56559482; called by muse, mutect2, varscan2
- MORF4L1 | c.302T>A p.V101E (on ENST00000331268 / NM_206839.2; = p.V62E on NM_006791.4) | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV100489053; called by muse, mutect2, varscan2
- NBEA | c.4882G>A p.A1628T | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated, low confidence (0.24); PolyPhen probably damaging (0.956); catalogued as COSV59834637; called by muse, mutect2, varscan2
- NCAM2 | c.1043A>G p.K348R | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as COSV99522284; called by muse, mutect2, varscan2
- NDUFA9 | c.199C>T p.R67* | Nonsense Mutation (SNP) | VAF 13/87 reads (15%) | catalogued as rs758574474, COSV99865411; called by muse, mutect2, varscan2
- NLRC3 | c.601G>A p.V201I | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs777640003, COSV57097959; called by muse, varscan2
- NOL11 | c.451G>T p.E151* | Nonsense Mutation (SNP) | VAF 18/81 reads (22%) | catalogued as COSV53523080, COSV99474928; called by muse, mutect2, varscan2
- NR0B2 | c.398G>A p.G133D | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.09); catalogued as COSV99574969; called by muse, mutect2
- NUAK1 | c.1229G>A p.R410H | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.648); catalogued as rs771843801, COSV54602649; called by muse, mutect2, varscan2
- OLFML2B | c.2167C>T p.Q723* | Nonsense Mutation (SNP) | VAF 21/142 reads (15%) | catalogued as COSV99668225; called by muse, mutect2, varscan2
- OPHN1 | c.302G>T p.R101M | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100830315; called by muse, mutect2, varscan2
- OR2B6 | c.164T>C p.L55P | Missense Mutation (SNP) | VAF 25/172 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs780961784, COSV99773666; called by muse, mutect2, varscan2
- OR4C16 | c.353T>C p.V118A | Missense Mutation (SNP) | VAF 47/159 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as rs74994489; called by muse, mutect2, varscan2
- PAPPA2 | c.4671A>T p.K1557N | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.259); catalogued as COSV100867741; called by muse, mutect2, varscan2
- PAQR4 | c.698T>G p.F233C | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99233965; called by muse, mutect2, varscan2
- PASD1 | c.275A>C p.K92T | Missense Mutation (SNP) | VAF 47/85 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV64854599; called by muse, mutect2, varscan2
- PCDH15 | c.2127T>A p.D709E | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as rs996460868, COSV100218004; called by muse, mutect2, varscan2
- PCDHB9 | c.685C>T p.R229C | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.742); catalogued as rs782808992; called by muse, mutect2
- PCDHGA8 | c.1653C>A p.F551L | Missense Mutation (SNP) | VAF 75/140 reads (54%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.03); catalogued as COSV53979990, COSV99534236; called by muse, mutect2, varscan2
- PCLO | c.3598C>G p.L1200V | Missense Mutation (SNP) | VAF 21/105 reads (20%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.003); catalogued as COSV100429752; called by muse, mutect2, varscan2
- PFKFB4 | c.692C>T p.A231V | Missense Mutation (SNP) | VAF 46/89 reads (52%) | PolyPhen benign (0); catalogued as COSV99219481; called by muse, mutect2, varscan2
- PIKFYVE | c.2189A>C p.Q730P | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100010220; called by muse, mutect2, varscan2
- PLXNA3 | c.1846C>T p.R616W | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.685); catalogued as rs1285036721, COSV63754562; called by muse, mutect2, varscan2
- PPP1R21 | c.1102T>C p.C368R | Missense Mutation (SNP) | VAF 31/129 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.617); catalogued as rs763862675, COSV99681849; called by muse, mutect2, varscan2
- PRKCB | c.1319A>G p.E440G | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100333067; called by muse, mutect2, varscan2
- PROM2 | c.2247G>C p.V749= | Splice Region (SNP) | VAF 17/65 reads (26%) | catalogued as COSV100468820; called by muse, mutect2, varscan2
- PRSS16 | c.1472G>A p.R491H | Missense Mutation (SNP) | VAF 42/82 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs753745230, COSV100041628, COSV57916245; called by muse, mutect2, varscan2
- RAB3GAP2 | c.3389C>T p.A1130V | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.178); catalogued as rs369410531; called by muse, mutect2, varscan2
- RASSF6 | c.837G>C p.K279N (on ENST00000342081 / NM_201431.2; = p.K247N on NM_177532.5) | Missense Mutation (SNP) | VAF 22/260 reads (8%) | SIFT tolerated (0.51); PolyPhen benign (0.068); catalogued as COSV100274852; called by muse, mutect2
- RGS10 | c.521G>T p.*174Lext*60 (on ENST00000369101; = p.*168Lext*60 on NM_002925.3) | Nonstop Mutation (SNP) | VAF 40/106 reads (38%) | catalogued as COSV100962175; called by muse, mutect2, varscan2
- ROBO1 | c.1211G>T p.R404L | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101458444; called by muse, varscan2
- ROBO2 | c.2050T>C p.W684R | Missense Mutation (SNP) | VAF 31/69 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100165380; called by muse, mutect2, varscan2
- RPTOR | c.628G>A p.A210T | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.461); catalogued as rs560409938, COSV100155748; called by muse, mutect2, varscan2
- RUFY3 | c.983G>A p.R328Q | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0.018); catalogued as rs758649386, COSV99887092; called by muse, mutect2
- SCO2 | c.283C>T p.R95C | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs748973032, COSV52689123; called by muse, mutect2, varscan2
- SEMA3D | c.4A>C p.N2H | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.067); catalogued as COSV52403818, COSV99406239; called by muse, mutect2, varscan2
- SEMA3D | c.3G>C p.M1? | Translation Start Site (SNP) | VAF 7/42 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.48); catalogued as COSV99406240; called by muse, mutect2, varscan2
- SLC7A4 | c.1442C>T p.A481V | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.07); catalogued as rs774611835, COSV60383101; called by muse, mutect2, varscan2
- SLCO1C1 | c.2020A>C p.S674R | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as COSV56869580; called by muse, mutect2, varscan2
- TAF8 | c.728C>T p.S243L | Missense Mutation (SNP) | VAF 19/121 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs752586050, COSV65896570; called by muse, mutect2, varscan2
- TBL2 | c.1063C>T p.H355Y | Missense Mutation (SNP) | VAF 17/120 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99979545; called by muse, mutect2, varscan2
- TMEM184A | c.583G>A p.V195I | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.98); PolyPhen benign (0.01); catalogued as rs923567693, COSV52474866; called by muse, mutect2, varscan2
- TRIM3 | c.505G>A p.V169M | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); catalogued as COSV100624307; called by muse, mutect2, varscan2
- TRPA1 | c.1736A>G p.Q579R | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT tolerated (0.36); PolyPhen benign (0.081); catalogued as COSV100083651; called by muse, mutect2, varscan2
- TRPC6 | c.1542G>C p.W514C | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100723528; called by muse, mutect2, varscan2
- TRPV4 | c.811C>T p.R271C | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as rs1227793261, COSV99924534; called by muse, mutect2, varscan2
- UBQLN2 | c.490T>G p.F164V | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100592673; called by muse, mutect2, varscan2
- VCPKMT | c.68G>A p.R23Q | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as COSV99365711; called by muse, mutect2, varscan2
- WDR49 | c.1921A>G p.K641E (on ENST00000308378 / NM_001366158.1; = p.K982E on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 62/234 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100392197; called by muse, mutect2, varscan2
- ZFHX4 | c.9881A>G p.E3294G | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99260151; called by mutect2, varscan2
- ZHX2 | c.1350G>C p.Q450H | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.159); catalogued as COSV100072791; called by muse, mutect2, varscan2
- ZNF570 | c.1181C>A p.A394D | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV100356098; called by muse, mutect2, varscan2
- ZNF573 | c.709G>C p.E237Q (on ENST00000536220 / NM_001172692.1; = p.E179Q on NM_152360.3) | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.279); catalogued as COSV59823787; called by muse, mutect2, varscan2
- ZRANB3 | c.278C>T p.P93L | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.223); catalogued as COSV99923127, COSV99924969; called by muse, mutect2, varscan2
- CASKIN1 | c.850del p.L284Cfs*15 | Frame Shift Del (DEL) | VAF 9/67 reads (13%) | called by mutect2, pindel, varscan2
- CEACAM5 | c.516_518dup p.Q172_D173insE | In Frame Ins (INS) | VAF 28/114 reads (25%) | called by mutect2, pindel, varscan2
- PABPN1 | c.493_495del p.E165del | In Frame Del (DEL) | VAF 19/91 reads (21%) | called by pindel, varscan2
- PRAMEF20 | c.354A>C p.E118D | Missense Mutation (SNP) | VAF 144/375 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- SAMD9L | c.3521dup p.N1174Kfs*3 | Frame Shift Ins (INS) | VAF 73/343 reads (21%) | called by mutect2, pindel, varscan2
- ADAMTSL3 | c.795C>T p.A265= | Silent (SNP) | VAF 8/63 reads (13%) | catalogued as COSV99717831; called by muse, mutect2, varscan2
- AHNAK | c.9621C>T p.F3207= | Silent (SNP) | VAF 46/295 reads (16%) | catalogued as COSV57205034; called by muse, mutect2, varscan2
- ALAD | c.822C>T p.A274= | Silent (SNP) | VAF 7/17 reads (41%) | catalogued as rs371639473; called by muse, mutect2, varscan2
- ALMS1 | c.11199T>G p.T3733= | Silent (SNP) | VAF 16/55 reads (29%) | catalogued as COSV100041805; called by muse, mutect2, varscan2
- ASXL3 | c.6228T>C p.C2076= | Silent (SNP) | VAF 29/53 reads (55%) | catalogued as rs760737437, COSV99324092; called by muse, mutect2, varscan2
- CCL11 | c.99C>T p.C33= | Silent (SNP) | VAF 11/45 reads (24%) | catalogued as COSV100005501; called by muse, mutect2, varscan2
- CCNB3 | c.1686T>A p.S562= | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as COSV99328752; called by muse, mutect2, varscan2
- ELAPOR2 | c.1149T>G p.A383= (on ENST00000450689 / NM_001142749.3; = p.A216= on NM_152748.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 18/113 reads (16%) | catalogued as COSV99788490; called by muse, mutect2, varscan2
- FEZF2 | c.1104A>G p.K368= | Silent (SNP) | VAF 17/36 reads (47%) | catalogued as COSV99334604; called by muse, mutect2, varscan2
- GABRA4 | c.1530T>G p.P510= | Silent (SNP) | VAF 24/114 reads (21%) | catalogued as COSV51926115; called by muse, mutect2, varscan2
- GABRB1 | c.1242C>T p.Y414= | Silent (SNP) | VAF 27/92 reads (29%) | catalogued as rs1422494010, COSV54979613, COSV99780315; called by muse, mutect2, varscan2
- GHR | c.1524G>A p.K508= | Silent (SNP) | VAF 19/40 reads (48%) | catalogued as COSV100050260; called by muse, mutect2, varscan2
- GNAS | c.846C>A p.G282= | Silent (SNP) | VAF 11/29 reads (38%) | catalogued as COSV100005920; called by muse, mutect2, varscan2
- IRAK2 | c.1776T>G p.T592= | Silent (SNP) | VAF 26/51 reads (51%) | catalogued as rs771895715, COSV99843849; called by muse, mutect2, varscan2
- ISCU | c.393T>C p.L131= (on ENST00000311893 / NM_213595.4; = p.L106= on NM_014301.4) | Silent (SNP) | VAF 17/63 reads (27%) | catalogued as COSV100318292; called by muse, mutect2, varscan2
- JARID2 | c.2316C>T p.S772= | Silent (SNP) | VAF 55/99 reads (56%) | catalogued as rs745772893, COSV100521601; called by muse, mutect2, varscan2
- KIF2B | c.1236T>G p.T412= | Silent (SNP) | VAF 21/55 reads (38%) | catalogued as COSV99275003; called by muse, mutect2, varscan2
- MARCHF4 | c.777T>G p.T259= | Silent (SNP) | VAF 22/97 reads (23%) | catalogued as COSV99814197; called by muse, mutect2, varscan2
- NID1 | c.2655G>A p.A885= | Silent (SNP) | VAF 7/16 reads (44%) | catalogued as rs1274749804, COSV99937263; called by muse, mutect2, varscan2
- NME5 | c.579G>A p.L193= | Silent (SNP) | VAF 17/37 reads (46%) | catalogued as COSV99496769; called by muse, mutect2, varscan2
- NMNAT2 | c.393C>T p.N131= | Silent (SNP) | VAF 7/38 reads (18%) | catalogued as rs748028043, COSV54268193; called by muse, mutect2, varscan2
- PAX6 | c.321G>T p.L107= | Silent (SNP) | VAF 39/116 reads (34%) | catalogued as COSV99570256; called by muse, mutect2, varscan2
- PRKDC | c.10290T>C p.N3430= | Silent (SNP) | VAF 18/57 reads (32%) | catalogued as COSV100039382; called by muse, mutect2, varscan2
- RBMX2 | c.789G>A p.K263= | Silent (SNP) | VAF 17/42 reads (40%) | catalogued as COSV100564750; called by muse, mutect2, varscan2
- SACS | c.13260C>T p.C4420= | Silent (SNP) | VAF 40/108 reads (37%) | catalogued as rs1280171268, COSV66539123; called by muse, mutect2, varscan2
- SIX3 | c.618C>T p.G206= | Silent (SNP) | VAF 3/29 reads (10%) | catalogued as rs1160056413, CX102534, COSV99578195; called by muse, mutect2
- SLC22A23 | c.1155C>T p.H385= | Silent (SNP) | VAF 14/94 reads (15%) | catalogued as COSV100978167; called by muse, mutect2, varscan2
- SMC1B | c.2718G>T p.G906= | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as COSV100663100; called by muse, mutect2, varscan2
- SPTBN4 | c.5298G>A p.Q1766= | Silent (SNP) | VAF 13/34 reads (38%) | catalogued as COSV58945442; called by muse, mutect2, varscan2
- STIL | c.1665C>T p.P555= | Silent (SNP) | VAF 19/111 reads (17%) | catalogued as COSV99680755, COSV99680793; called by muse, mutect2, varscan2
- TEX11 | c.1602G>A p.E534= (on ENST00000344304; = p.E519= on NM_031276.3) | Silent (SNP) | VAF 24/63 reads (38%) | catalogued as COSV100721302, COSV60228036; called by muse, mutect2, varscan2
- ZAP70 | c.292C>T p.L98= | Silent (SNP) | VAF 3/27 reads (11%) | called by muse, mutect2
- ZFP30 | c.54A>G p.E18= | Silent (SNP) | VAF 17/74 reads (23%) | catalogued as COSV100665836; called by muse, mutect2, varscan2
- ZIC5 | c.1992G>A p.*664= | Silent (SNP) | VAF 9/46 reads (20%) | catalogued as COSV57436975, COSV57439092; called by muse, mutect2
- MACF1 | c.16491+622C>T | Intron (SNP) | VAF 5/22 reads (23%) | catalogued as rs760337316, COSV57114541; called by muse, mutect2, varscan2
- ZSCAN32 | c.914+113A>G | Intron (SNP) | VAF 23/64 reads (36%) | catalogued as COSV100514265; called by muse, mutect2, varscan2
